CCDI case PBBUMH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8bb7223b-ae1d-4cf9-bb2a-01741396fb7e

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.9 years (1,419 days).

Biospecimens (3 samples)
- Sample 0DHHJ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DHHLL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI8M8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
